Gene-level copy-number profile of tumor specimen TCGA-FJ-A3Z7-01A from TCGA case TCGA-FJ-A3Z7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.8 years (28,052 days).
Specimen TCGA-FJ-A3Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cd735f43-7a6c-494d-8bdf-d764ef89c0de.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FJ-A3Z7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85b233b7-54da-4943-b2e4-b30a6e894da6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 2,629; copy number 2: 8,963; copy number 3: 21,300; copy number 4: 9,385; copy number 5: 11,313; copy number 6: 2,214; copy number 7: 854; copy number 8: 1,361; copy number 9: 627; copy number 10: 330; copy number 11: 171; copy number 12: 131; copy number 13: 120; copy number 14: 86; copy number 15: 221; copy number 17: 2; copy number 18: 31; copy number 21: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FJ-A3Z7-01A-12D-A23L-01): tumor purity 0.54, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:15,928,296–16,815,688, 15 genes (within-gene range 0–2): MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1.
- chr21:17,210,469–17,894,485, 19 genes: NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3.
- chr21:19,593,841–22,438,349, 28 genes: RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,947 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,862,672–6,261,098, 12 genes, copy number 9: MIR4689, NPHP4, KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153.
- chr1:29,192,657–31,509,648, 40 genes, copy number 7–15: MECR, AL590729.1, PTPRU, LINC01756, AL671862.1, AC092265.1, AL645944.2, AL645944.1, LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2, ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA.
- chr1:38,991,276–45,513,382, 229 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr1:147,019,656–148,255,012, 44 genes, copy number 14 (within-gene range 4–14): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2.
- chr1:149,754,301–150,975,534, 68 genes, copy number 15 (broad region; genes not listed).
- chr1:160,115,759–164,899,296, 141 genes, copy number 7–14 (broad region; genes not listed).
- chr1:168,695,874–176,845,601, 161 genes, copy number 8–21 (within-gene range 6–21) (broad region; genes not listed).
- chr1:183,138,402–185,335,039, 48 genes, copy number 9–13: LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, AL713852.2, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1.
- chr3:4,896,809–35,872,198, 425 genes, copy number 8–15 (broad region; genes not listed).
- chr5:4,967,764–12,804,363, 143 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr5:32,887,990–42,191,523, 153 genes, copy number 7–8 (broad region; genes not listed).
- chr5:42,465,400–42,468,868, 1 gene, copy number 7 (within-gene range 4–7): SERBP1P6.
- chr5:44,066,624–45,895,970, 16 genes, copy number 8: RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr5:98,768,650–98,798,643, 1 gene, copy number 9 (within-gene range 2–9): RGMB.
- chr5:98,792,861–98,995,013, 7 genes, copy number 9: AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1.
- chr6:9,596,110–24,365,754, 206 genes, copy number 7–18 (broad region; genes not listed).
- chr6:102,350,271–107,051,586, 50 genes, copy number 8–14: AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1.
- chr6:137,657,998–139,860,476, 41 genes, copy number 7 (within-gene range 4–7): AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1.
- chr6:151,364,115–152,129,619, 11 genes, copy number 7: ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1.
- chr7:70,972–5,854,365, 130 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:11,370,365–11,832,198, 1 gene, copy number 7 (within-gene range 6–7): THSD7A.
- chr7:11,820,317–21,901,839, 111 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:25,431,980–25,756,256, 5 genes, copy number 12 (within-gene range 5–12): AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3.
- chr7:28,953,358–34,878,332, 110 genes, copy number 8–18 (within-gene range 5–18) (broad region; genes not listed).
- chr8:69,667,046–103,002,424, 561 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr9:14,475–13,323,450, 173 genes, copy number 7–17 (broad region; genes not listed).
- chr9:16,203,935–19,786,928, 41 genes, copy number 7: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1, SAXO1, AL356000.1, RRAGA, HAUS6, SCARNA8, RNU6-264P, Y_RNA, PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1.
- chr9:29,824,742–30,575,012, 3 genes, copy number 7: ME2P1, LINC01242, SLC4A1APP1.
- chr9:30,935,485–30,990,572, 2 genes, copy number 7: FTLP4, HSPA8P17.
- chr10:44,712–3,502,915, 57 genes, copy number 7 (within-gene range 5–7): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669.
- chr11:12,619,326–15,247,208, 47 genes, copy number 8: AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC.
- chr11:25,734,757–50,422,316, 429 genes, copy number 8 (broad region; genes not listed).
- chr19:10,037,803–11,980,617, 116 genes, copy number 7 (broad region; genes not listed).
- chr19:11,996,809–11,996,916, 1 gene, copy number 7: RNA5SP464.
- chr20:7,977,346–9,839,076, 15 genes, copy number 7 (within-gene range 2–7): TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1.
- chr21:22,882,582–23,432,282, 11 genes, copy number 7: AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA.
- chr21:24,840,550–28,228,667, 53 genes, copy number 7–13 (within-gene range 5–13): LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695.
- chr21:28,872,191–28,992,956, 4 genes, copy number 7: N6AMT1, HSPD1P7, THUMPD1P1, LTN1.
- chr21:30,263,380–32,771,792, 82 genes, copy number 7 (broad region; genes not listed).
- chr21:41,679,181–46,665,124, 197 genes, copy number 8–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,442. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
